Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3713, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3713-01A (Primary Tumor).

Diagnosis:

This is a moderately differentiated invasive adenocarcinoma of the colon with focal penetration of the tunica muscularis and infiltration of the pericolic fatty tissue. The surface of the tumor shows necroses, in the periphery of the tumor is a moderate lymphocytic inflammatory reaction. The oral resection margin shows a normal, tumor-free ileum wall; the aboral resection margin shows a tumor-free colon wall. The area of the central vascular ligature is tumor-free.

The polyps described are tubulovillous adenomas, in some cases with slight dysplasia.

The omentum shows the metastasis of a poorly differentiated mucinous adenocarcinoma. The differentiation of this adenocarcinoma differs markedly from the adenocarcinoma in the right flexure (but see III).

The 15 lymph nodes are tumor-free and show reactive hyperplasia.

Tumor classification:

ICDO-DA-M 8140/3

pT3, pN0, R0 / G2.

Source: NCI Genomic Data Commons file c6293a72-ddfa-4481-845b-03e0215ee9ed (TCGA-AA-3713.DC1F9CD6-4FBE-4CE7-8D6C-A67F3266448E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).